Somatic mutation profile of tumor specimen TCGA-WB-A81T-01A (aliquot TCGA-WB-A81T-01A-11D-A35I-08) from TCGA case TCGA-WB-A81T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.2 years (16,506 days).
Specimen TCGA-WB-A81T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ead513d-2bdf-4757-b7c9-23e07b4224a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81T-10A (Blood Derived Normal), aliquot TCGA-WB-A81T-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/227a2c0f-9e47-4656-9e3e-43fca9c0f226

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UBXN6 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56674438; called by muse, mutect2
- VPS37A | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1391557682; called by muse, mutect2, varscan2
- ANK3 | c.11512C>T p.H3838Y | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANK3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COG3 | c.1849_1868delinsC p.I618Lfs*27 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2*
- DAB2IP | c.1801C>T p.L601F (on ENST00000408936; = p.L573F on NM_032552.3) | Missense Mutation (SNP) | VAF 71/106 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- EYA3 | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- IDE | c.2760A>T p.R920S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- MCUR1 | c.908T>C p.L303S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TFAP2D | c.467T>A p.M156K | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VSIG4 | c.56-2A>G p.X19_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- DGLUCY | c.552C>T p.L184= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs758724876; called by muse, mutect2
- MGAM | c.1275T>C p.Y425= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs1554462884; called by muse, mutect2, varscan2
- RAB6A | c.597A>G p.Q199= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- TMEM98 | c.174G>A p.E58= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs769334535, COSV99912897; called by muse, mutect2, varscan2
- USP17L2 | c.325C>T p.L109= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs761267593, COSV61556707; called by muse, mutect2, varscan2
